Somatic mutation profile of tumor specimen ALCH-B27Q-TTP1-A (aliquot ALCH-B27Q-TTP1-A-1-0-D-A775-36) from ALCHEMIST case ALCH-B27Q, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 57.4 years (20,956 days).
Specimen ALCH-B27Q-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9b7dcab-6851-4847-bb25-aa556f98c7ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B27Q-NB1-A (Blood Derived Normal), aliquot ALCH-B27Q-NB1-A-1-0-D-A775-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4eddd497-66ae-4947-9931-81c551203096

The open-access MAF lists 730 somatic variants for this specimen: 494 protein-altering or splice-affecting, 162 silent, 74 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 437, Silent 162, Nonsense Mutation 33, Intron 25, RNA 15, 5'UTR 14, Frame Shift Del 12, 3'UTR 9, Splice Site 8, 5'Flank 8, Splice Region 4, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC20A2 | c.1723G>T p.E575* | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as rs387906653, CM121621, COSV60601673; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 137/319 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ACAP1 | c.1614del p.Q539Sfs*17 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as rs774869688; called by mutect2, varscan2
- ADAMTS19 | c.1573G>T p.V525F | Missense Mutation (SNP) | VAF 62/181 reads (34%) | SIFT tolerated (0.61); PolyPhen probably damaging (1); catalogued as COSV50740351; called by muse, mutect2, varscan2
- ADGRG6 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 60/323 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51590624; called by muse, mutect2, varscan2
- AGRN | c.5992G>T p.E1998* | Nonsense Mutation (SNP) | VAF 43/192 reads (22%) | catalogued as rs1391410827, COSV101039116; called by muse, mutect2, varscan2
- ANK2 | c.2144C>A p.T715N | Missense Mutation (SNP) | VAF 52/288 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as rs199681788; called by muse, mutect2, varscan2
- APLNR | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs200201854; called by muse, mutect2, varscan2
- APOC1 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs964053456; called by muse, mutect2
- ASPDH | c.402C>G p.I134M | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV65350473; called by muse, mutect2, varscan2
- C6 | c.2249C>A p.S750Y | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54705755, COSV99667107; called by muse, mutect2, varscan2
- CACNA1E | c.3639G>T p.Q1213H | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62381990; called by muse, mutect2
- CACNA1H | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.983); catalogued as rs924641282; called by muse, mutect2, varscan2
- CACNG8 | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 57/390 reads (15%) | catalogued as COSV54416137; called by muse, mutect2, varscan2
- CALHM5 | c.678G>T p.L226F | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV62068789; called by muse, mutect2, varscan2
- CBFB | c.534G>T p.K178N | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV51998385; called by muse, mutect2, varscan2
- CCN2 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 68/263 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.024); catalogued as rs771227127; called by muse, mutect2, varscan2
- CCN4 | c.610+1del | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as COSV51529438, COSV99137085; called by mutect2, pindel, varscan2
- CD163L1 | c.2449C>A p.R817S | Missense Mutation (SNP) | VAF 81/222 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV58015762; called by muse, mutect2, varscan2
- CDC7 | c.850C>G p.R284G | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769620136, COSV52311818, COSV99319660; called by muse, mutect2, varscan2
- CELA1 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 25/128 reads (20%) | catalogued as rs1384814685; called by muse, mutect2, varscan2
- CHAD | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.232); catalogued as COSV51970789; called by muse, mutect2, varscan2
- CHRNB2 | c.1463C>T p.T488I | Missense Mutation (SNP) | VAF 198/482 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.038); catalogued as rs796052328; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNGA3 | c.1013C>A p.P338Q | Missense Mutation (SNP) | VAF 66/215 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV55623032; called by muse, mutect2, varscan2
- COL22A1 | c.566C>A p.A189D | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100279859; called by muse, mutect2, varscan2
- COL28A1 | c.416A>G p.N139S | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1039050204; called by muse, mutect2, varscan2
- CPSF6 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 29/252 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.361); catalogued as COSV57018650; called by muse, mutect2, varscan2
- CR2 | c.925C>A p.P309T | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100889507; called by muse, mutect2, varscan2
- CSF3R | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58963648, COSV58964839; called by muse, mutect2, varscan2
- CSNK1E | c.46G>T p.G16W | Missense Mutation (SNP) | VAF 93/189 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100725023; called by muse, mutect2, varscan2
- CTU1 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1395257773; called by muse, mutect2
- CWH43 | c.553G>T p.V185L | Missense Mutation (SNP) | VAF 69/187 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV56942845; called by muse, mutect2, varscan2
- DDX27 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.103); catalogued as rs1015161373; called by muse, mutect2, varscan2
- DMP1 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.517); catalogued as rs765884882, COSV99031069; called by muse, mutect2, varscan2
- DOCK4 | c.2479C>T p.R827* | Nonsense Mutation (SNP) | VAF 28/104 reads (27%) | catalogued as rs1283720924, COSV101447941; called by muse, mutect2, varscan2
- DOCK9 | c.268C>T p.R90* (on ENST00000376460 / NM_001366676.2; = p.R91* on NM_015296.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 54/298 reads (18%) | catalogued as COSV104412265; called by muse, mutect2, varscan2
- ERICH3 | c.2606G>T p.G869V | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.339); catalogued as COSV100445748; called by muse, mutect2, varscan2
- ESRRG | c.1371G>T p.K457N | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as COSV63151410, COSV63173476; called by muse, mutect2, varscan2
- ETFBKMT | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1402753330; called by muse, mutect2, varscan2
- EYS | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV60981397; called by muse, mutect2, varscan2
- F2 | c.1471A>G p.S491G | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as rs558750141; called by muse, mutect2, varscan2
- FCRLA | c.313C>A p.L105I (on ENST00000367959; = p.L82I on NM_032738.4) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52684150; called by muse, mutect2, varscan2
- GABRG1 | c.356G>C p.W119S | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54954790; called by muse, mutect2, varscan2
- GLI4 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 99/230 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.521); catalogued as rs745456153, COSV100391002; called by muse, mutect2, varscan2
- GRB10 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 34/326 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); catalogued as COSV60009685; called by muse, mutect2
- GRIA1 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as rs751038792; called by muse, mutect2, varscan2
- GRIA3 | c.616A>G p.I206V | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as rs753347543; called by muse, mutect2, varscan2
- GRID2 | c.2467G>A p.G823R | Missense Mutation (SNP) | VAF 56/318 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376767575; called by muse, mutect2, varscan2
- HEATR6 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.097); catalogued as rs761835181, COSV99482416; called by muse, mutect2, varscan2
- HECTD4 | c.10522G>T p.D3508Y | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.771); catalogued as rs1285348526, COSV101107259; called by muse, mutect2, varscan2
- HMGB4 | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 45/239 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV53898520; called by muse, mutect2, varscan2
- HOOK1 | c.1950T>C p.S650= | Splice Region (SNP) | VAF 25/127 reads (20%) | catalogued as rs140000589; called by muse, mutect2, varscan2
- IGHA1 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 53/359 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs751134136; called by muse, mutect2, varscan2
- IGKJ3 | c.7A>T p.T3S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as rs753240107; called by muse, mutect2, varscan2
- IGKV1-5 | c.113G>C p.G38A | Missense Mutation (SNP) | VAF 107/469 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs543758965; called by muse, mutect2, varscan2
- KIAA1210 | c.2269G>T p.V757F | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.673); catalogued as COSV101274311; called by muse, mutect2, varscan2
- KIAA1614 | c.464G>A p.S155N | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as rs1214334803; called by muse, mutect2
- KIF26A | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs759188299, COSV99043674; called by muse, mutect2, varscan2
- KIF2B | c.1817G>T p.G606V | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV52129666; called by muse, varscan2
- KYAT3 | c.1225G>C p.A409P | Missense Mutation (SNP) | VAF 54/272 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53103480; called by muse, mutect2, varscan2
- LAMP5 | c.10C>A p.Q4K | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV55714893; called by muse, mutect2, varscan2
- LIG1 | c.1893G>T p.Q631H | Missense Mutation (SNP) | VAF 119/390 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs776170778; called by muse, mutect2, varscan2
- LINGO1 | c.686C>A p.A229D | Missense Mutation (SNP) | VAF 50/258 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV62436274; called by muse, mutect2, varscan2
- LMNB1 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.392); catalogued as COSV54397369; called by muse, mutect2, varscan2
- LMOD3 | c.1583del p.P528Hfs*12 | Frame Shift Del (DEL) | VAF 65/208 reads (31%) | catalogued as rs1367271303, COSV101342023; called by mutect2, pindel, varscan2
- LRRC37B | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV58954802; called by mutect2, varscan2
- LRRC37B | c.1142C>A p.S381Y | Missense Mutation (SNP) | VAF 43/309 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV58951133; called by muse, mutect2, varscan2
- MAGEC1 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 68/446 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); catalogued as COSV99594799; called by muse, varscan2
- MARCHF1 | c.255C>A p.C85* (on ENST00000274056; = p.C68* on NM_017923.4) | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as COSV56812512, COSV56819636; called by muse, mutect2, varscan2
- MELTF | c.1349C>T p.S450L | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.404); catalogued as rs1183723830; called by muse, mutect2
- MERTK | c.2254G>A p.D752N | Missense Mutation (SNP) | VAF 95/297 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs750451461; called by muse, mutect2, varscan2
- MGAT3 | c.1384G>T p.G462W | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100362134; called by muse, mutect2, varscan2
- MICALL2 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs780791238; called by muse, mutect2, varscan2
- MLLT10 | c.2492A>G p.N831S (on ENST00000307729 / NM_001195626.3; = p.N847S on NM_004641.3) | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.522); catalogued as rs745767811, COSV56996581; called by muse, mutect2, varscan2
- MME | c.1115C>A p.S372Y | Missense Mutation (SNP) | VAF 21/376 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV100852451; called by muse, mutect2
- MON1B | c.1549G>T p.D517Y | Missense Mutation (SNP) | VAF 47/372 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99941847; called by muse, mutect2, varscan2
- MORN1 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.722); catalogued as rs752413949, COSV101047313; called by muse, mutect2, varscan2
- MPO | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1015188690; called by muse, mutect2
- MSMO1 | c.804G>T p.W268C | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV54970090; called by muse, mutect2
- MUC16 | c.38714C>G p.S12905C | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.957); catalogued as rs371311674; called by muse, mutect2
- MUC16 | c.36145G>T p.V12049L | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.679); catalogued as COSV67463434; called by muse, mutect2, varscan2
- MYLK | c.867G>T p.E289D | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.878); catalogued as COSV60605247; called by muse, mutect2
- MYO3B | c.3778C>T p.R1260* | Nonsense Mutation (SNP) | VAF 22/222 reads (10%) | catalogued as rs1559205741; called by muse, mutect2, varscan2
- MYO7B | c.3466G>A p.G1156S | Missense Mutation (SNP) | VAF 63/260 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.028); catalogued as rs954972165, COSV67347539; called by muse, mutect2, varscan2
- NLRP2 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779856359; called by muse, mutect2, varscan2
- NLRP9 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV60468831; called by muse, mutect2, varscan2
- NOTCH3 | c.6217G>T p.G2073W | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV54632985; called by muse, mutect2, varscan2
- NPBWR2 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs369032409; called by muse, mutect2, varscan2
- NPY5R | c.1151T>C p.L384P | Missense Mutation (SNP) | VAF 40/256 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770541555; called by muse, mutect2, varscan2
- NR0B2 | c.716C>A p.P239H | Missense Mutation (SNP) | VAF 68/316 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54259991; called by muse, mutect2, varscan2
- NRG3 | c.1339A>T p.S447C | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV64579994; called by muse, mutect2, varscan2
- NUDCD1 | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV53458262; called by muse, mutect2, varscan2
- OR11H1 | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 32/750 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1285670716; called by muse, mutect2
- OR14I1 | c.357C>A p.D119E | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61198868; called by muse, mutect2, varscan2
- OR2B3 | c.748C>A p.L250I | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.645); catalogued as COSV65850721; called by muse, mutect2, varscan2
- OR56A1 | c.896C>A p.T299N | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.973); catalogued as rs1231091438; called by muse, mutect2
- OR5T2 | c.399C>A p.F133L | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV57588295, COSV57589380; called by muse, varscan2
- OR6K2 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs778681132; called by muse, mutect2
- OR8H3 | c.932C>A p.S311Y | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV57911330; called by muse, mutect2, varscan2
- OTP | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV60568449; called by muse, mutect2, varscan2
- OTP | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100119925; called by muse, mutect2, varscan2
- PADI1 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 65/276 reads (24%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.963); catalogued as rs781378566, COSV64937727; called by muse, mutect2, varscan2
- PATL1 | c.2191G>A p.A731T | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs757362723; called by muse, varscan2
- PCLO | c.12815G>T p.R4272L | Missense Mutation (SNP) | VAF 78/360 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61658525; called by muse, varscan2
- PDE4B | c.1726C>T p.R576W | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs750670488, COSV58480136; called by muse, mutect2, varscan2
- PER3 | c.1043A>G p.D348G | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs745884057; called by muse, mutect2, varscan2
- PIGZ | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 61/260 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as COSV53014166; called by muse, mutect2, varscan2
- PKD1L1 | c.4153G>T p.G1385C | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV56959124, COSV99220651; called by muse, mutect2, varscan2
- PKHD1 | c.9031G>T p.A3011S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV61896471; called by muse, mutect2, varscan2
- PKHD1 | c.4149G>T p.Q1383H | Missense Mutation (SNP) | VAF 127/552 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV100583007; called by muse, mutect2, varscan2
- PKHD1L1 | c.3374G>A p.S1125N | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as rs756471466; called by muse, mutect2
- POTEE | c.2879C>A p.A960E | Missense Mutation (SNP) | VAF 55/378 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.822); catalogued as rs1362336739; called by mutect2, varscan2
- PTPRR | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as rs560187208, COSV51725383; called by muse, mutect2, varscan2
- RALYL | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 41/195 reads (21%) | catalogued as COSV101569324; called by muse, mutect2, varscan2
- RANBP6 | c.442A>G p.I148V | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs771419317; called by muse, mutect2, varscan2
- RAPGEF6 | c.3944G>A p.G1315E | Missense Mutation (SNP) | VAF 84/172 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.045); catalogued as rs759377013; called by muse, mutect2, varscan2
- RBMXL3 | c.1204G>A p.G402R | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as rs1287136853; called by muse, varscan2
- RCBTB2 | c.1490C>T p.S497L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs373552083; called by muse, mutect2, varscan2
- RECQL4 | c.2264G>A p.R755Q | Missense Mutation (SNP) | VAF 119/309 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.79); catalogued as rs747445357, COSV52882885; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REG1A | c.422C>A p.T141N | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52069705; called by muse, mutect2, varscan2
- RIMS2 | c.830G>T p.R277L (on ENST00000666250 / NM_001348490.2; = p.R85L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV51709377, COSV51721099; called by muse, mutect2, varscan2
- RPAP1 | c.3364C>T p.P1122S | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as COSV58537249; called by muse, mutect2, varscan2
- RPS9 | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV100256352; called by muse, mutect2, varscan2
- RSPO2 | c.205C>G p.R69G | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52641662; called by muse, mutect2, varscan2
- SDC2 | c.524A>T p.D175V | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1320254228; called by muse, mutect2
- SEMA5A | c.779G>C p.G260A | Missense Mutation (SNP) | VAF 195/627 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV66790190; called by muse, mutect2, varscan2
- SERINC1 | c.656A>G p.Y219C | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs145924073; called by muse, mutect2, varscan2
- SERPINB6 | c.1184C>T p.P395L (on ENST00000612421 / NM_001271823.2; = p.P376L on NM_004568.6) | Missense Mutation (SNP) | VAF 87/402 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369004254; called by muse, mutect2, varscan2
- SGSM1 | c.2502G>C p.Q834H (on ENST00000400359 / NM_001039948.4; = p.Q773H on NM_133454.3) | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as COSV63082736; called by muse, mutect2
- SLA2 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.326); catalogued as COSV53409940; called by muse, mutect2, varscan2
- SLC12A7 | c.2630G>A p.R877H | Missense Mutation (SNP) | VAF 59/234 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767894435; called by muse, varscan2
- SLC22A18 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303620906; called by muse, mutect2
- SLC24A5 | c.55C>A p.L19M | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.206); catalogued as rs373895181; called by muse, mutect2, varscan2
- SLC39A2 | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.166); catalogued as rs761273431; called by muse, mutect2, varscan2
- SLC7A14 | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV99200864; called by muse, mutect2
- SLC9A2 | c.730C>A p.L244M | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52135316; called by muse, mutect2, varscan2
- SNTA1 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.553); catalogued as COSV54130428; called by muse, mutect2, varscan2
- SNTG1 | c.743C>A p.S248Y | Missense Mutation (SNP) | VAF 74/299 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs768884987, COSV52426628; called by muse, mutect2, varscan2
- SPN | c.503C>A p.P168H | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); catalogued as COSV100788921; called by muse, mutect2, varscan2
- SPO11 | c.1184G>T p.W395L | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61996286; called by muse, mutect2, varscan2
- SPTBN1 | c.5594A>T p.E1865V | Missense Mutation (SNP) | VAF 57/230 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs780273253; called by muse, mutect2, varscan2
- SST | c.266C>A p.S89Y | Missense Mutation (SNP) | VAF 84/634 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV55030868; called by muse, mutect2, varscan2
- STYXL2 | c.2423C>G p.P808R | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781424729, COSV99610098; called by muse, mutect2, varscan2
- SULT1C4 | c.900C>A p.F300L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as COSV55597240; called by muse, mutect2
- SYCP1 | c.117C>A p.N39K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.519); catalogued as COSV65696837; called by muse, mutect2, varscan2
- TBC1D31 | c.1852C>G p.L618V | Missense Mutation (SNP) | VAF 95/266 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1297405344; called by muse, mutect2, varscan2
- TCF23 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 52/208 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs150714023; called by muse, mutect2, varscan2
- TENM4 | c.4744A>G p.I1582V | Missense Mutation (SNP) | VAF 98/253 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs758518569; called by muse, mutect2, varscan2
- TEX13C | c.2836C>G p.Q946E | Missense Mutation (SNP) | VAF 88/199 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV66745122; called by muse, mutect2, varscan2
- TMPRSS6 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 264/518 reads (51%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs201819965, COSV100696215; called by muse, mutect2, varscan2
- TNFRSF11A | c.955G>C p.A319P | Missense Mutation (SNP) | VAF 79/298 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.511); catalogued as COSV54025959; called by muse, mutect2, varscan2
- TRANK1 | c.2630C>T p.T877M | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs749482435; called by muse, mutect2, varscan2
- TRAPPC9 | c.1228G>T p.V410L | Missense Mutation (SNP) | VAF 111/584 reads (19%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.596); catalogued as rs774257540, COSV101227069; called by muse, mutect2, varscan2
- TRIM35 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.565); catalogued as rs1341015065; called by muse, mutect2, varscan2
- TRIM64C | c.593T>C p.L198P | Missense Mutation (SNP) | VAF 88/376 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101597811; called by muse, mutect2, varscan2
- TRIM67 | c.2022C>A p.S674R | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as rs769669995; called by muse, mutect2, varscan2
- TRNT1 | c.800T>C p.I267T | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as rs113909075; called by muse, mutect2, varscan2
- TSEN34 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748455127; called by muse, mutect2, varscan2
- TTN | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 80/491 reads (16%) | catalogued as rs1347415564, COSV60385937; called by muse, mutect2, varscan2
- UGGT1 | c.3832G>A p.V1278M | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs184244900, COSV52132329; called by muse, mutect2, varscan2
- UGT2A3 | c.317C>G p.S106* | Nonsense Mutation (SNP) | VAF 15/75 reads (20%) | catalogued as COSV52358690, COSV52363036; called by muse, mutect2, varscan2
- UGT2B28 | c.161C>A p.T54N | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV59433940; called by muse, mutect2, varscan2
- UNC13A | c.1444G>T p.G482W | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV53191621; called by muse, mutect2, varscan2
- WDR17 | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1157076253; called by muse, mutect2, varscan2
- WNT7B | c.451G>T p.G151C | Missense Mutation (SNP) | VAF 207/334 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59752233; called by muse, mutect2, varscan2
- ZNF229 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV52163664, COSV52164353; called by muse, mutect2, varscan2
- ZNF467 | c.1198G>T p.A400S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV57372852; called by muse, mutect2
- ZNF502 | c.1299A>T p.K433N | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56075005; called by muse, mutect2, varscan2
- ZNF519 | c.1620G>C p.R540S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs144602129; called by muse, mutect2, varscan2
- ZNF536 | c.497G>T p.R166M | Missense Mutation (SNP) | VAF 54/369 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100834877; called by muse, mutect2, varscan2
- ZNF608 | c.1914G>C p.K638N | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs959142950; called by muse, mutect2, varscan2
- ZNF69 | c.1139A>T p.K380I | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.868); catalogued as COSV60902834; called by muse, mutect2, varscan2
- ZNF732 | c.112A>G p.R38G | Missense Mutation (SNP) | VAF 87/248 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs371346541; called by muse, mutect2, varscan2
- ZNF804B | c.3935C>G p.P1312R | Missense Mutation (SNP) | VAF 47/262 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100302937; called by muse, mutect2, varscan2
- ZNF99 | c.2274G>C p.E758D | Missense Mutation (SNP) | VAF 109/572 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as COSV68055812; called by muse, mutect2, varscan2
- AARS1 | c.1045T>G p.L349V | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCB5 | c.1126G>T p.G376* | Nonsense Mutation (SNP) | VAF 66/222 reads (30%) | called by muse, varscan2
- ABL2 | c.2099G>C p.G700A (on ENST00000502732 / NM_007314.4; = p.G685A on NM_005158.5) | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.018); called by muse, mutect2
- AC006059.2 | c.924G>T p.Q308H | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- AC026316.4 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 98/282 reads (35%) | PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ACCS | c.1502G>T p.R501M | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- ACSM2B | c.652A>T p.I218F | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ACSM4 | c.1360G>A p.G454R | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTN1 | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2
- ADAM23 | c.912G>C p.M304I | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.226); called by muse, varscan2
- ADAM23 | c.1031G>T p.R344M | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAM29 | c.2382G>T p.Q794H | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- ADAM7 | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- ADGRF5 | c.2125G>A p.V709I | Missense Mutation (SNP) | VAF 63/272 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ADGRG4 | c.674C>A p.T225K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, varscan2
- ADGRG7 | c.191T>A p.I64N | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AGBL2 | c.518A>G p.K173R | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP12 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ALDH3B1 | c.814T>A p.Y272N | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- ALDH8A1 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ALDH8A1 | c.949G>T p.G317C | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANKRD17 | c.3450G>T p.K1150N | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ANKS1B | c.1822C>A p.L608M | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANLN | c.1049G>T p.R350I | Missense Mutation (SNP) | VAF 68/225 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- APOH | c.472C>G p.P158A | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ARAF | c.853G>T p.A285S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP23 | c.2678A>G p.K893R | Missense Mutation (SNP) | VAF 73/171 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- ARHGEF4 | c.283C>A p.H95N | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARHGEF9 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARID1B | c.2363A>T p.Q788L | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- ARNT | c.1480A>T p.M494L | Missense Mutation (SNP) | VAF 65/192 reads (34%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASIC4 | c.1231C>A p.Q411K (on ENST00000347842 / NM_182847.3; = p.Q430K on NM_018674.6) | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ASMT | c.444-1G>T p.X148_splice | Splice Site (SNP) | VAF 49/366 reads (13%) | called by muse, mutect2, varscan2
- ATF3 | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.054); called by muse, mutect2
- ATN1 | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- ATPAF2 | c.372G>T p.K124N | Missense Mutation (SNP) | VAF 262/556 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- AUTS2 | c.3335C>T p.A1112V | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- B4GALT6 | c.1017G>T p.R339S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- B4GALT6 | c.1016G>T p.R339M | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- BRPF3 | c.1747_1748del p.Q583Afs*39 | Frame Shift Del (DEL) | VAF 24/121 reads (20%) | called by mutect2, pindel, varscan2
- CACNA1A | c.2872G>T p.E958* | Nonsense Mutation (SNP) | VAF 37/134 reads (28%) | called by muse, mutect2, varscan2
- CAD | c.3846G>T p.M1282I | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CAD | c.5263G>A p.E1755K | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CAD | c.5485G>A p.E1829K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- CATSPERB | c.2876A>G p.N959S | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCL1 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 38/496 reads (8%) | SIFT tolerated (0.96); PolyPhen benign (0.006); called by muse, mutect2
- CD163L1 | c.2950C>A p.L984I | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH2 | c.2398G>T p.A800S | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- CEBPE | c.763C>A p.Q255K | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- CFAP221 | c.511G>T p.V171F | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CFAP69 | c.2813G>T p.S938I | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHL1 | c.3364G>T p.D1122Y (on ENST00000397491 / NM_001253387.1; = p.D1138Y on NM_006614.4) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHML | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 73/230 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CLEC4D | c.148A>T p.K50* | Nonsense Mutation (SNP) | VAF 54/193 reads (28%) | called by muse, mutect2, varscan2
- CNTNAP1 | c.68-1G>T p.X23_splice | Splice Site (SNP) | VAF 74/180 reads (41%) | called by muse, mutect2, varscan2
- COL14A1 | c.1913A>G p.D638G | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- COL16A1 | c.278del p.P93Lfs*12 | Frame Shift Del (DEL) | VAF 23/124 reads (19%) | called by mutect2, pindel, varscan2
- CPB1 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CPT1C | c.2312G>T p.R771L | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CRPPA | c.631A>G p.S211G | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSRNP3 | c.745G>T p.G249* | Nonsense Mutation (SNP) | VAF 27/144 reads (19%) | called by muse, mutect2, varscan2
- CYP4A11 | c.1273T>A p.W425R | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- CYSLTR2 | c.467G>A p.W156* | Nonsense Mutation (SNP) | VAF 29/138 reads (21%) | called by muse, mutect2, varscan2
- DDAH2 | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 89/344 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- DENND4C | c.3529G>T p.V1177L (on ENST00000434457 / NM_001330640.2; = p.V1128L on NM_017925.7) | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- DGCR8 | c.1324A>T p.S442C | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.103); called by muse, mutect2
- DMC1 | c.569A>G p.Y190C | Missense Mutation (SNP) | VAF 32/362 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.786); called by muse, mutect2
- DMXL2 | c.851G>T p.C284F | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT tolerated (0.88); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- DNAH5 | c.10552G>T p.V3518L | Missense Mutation (SNP) | VAF 81/512 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH9 | c.8974G>T p.V2992F | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJB8 | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- DOCK1 | c.383G>T p.W128L | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- DSG4 | c.2601C>G p.D867E | Missense Mutation (SNP) | VAF 64/199 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ECHDC3 | c.316G>T p.G106W | Missense Mutation (SNP) | VAF 53/300 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EFHC1 | c.389G>A p.S130N | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- EFNB2 | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- EPX | c.820C>A p.R274S | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERVFRD-1 | c.737C>A p.A246D | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- ETNK1 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 40/121 reads (33%) | called by muse, mutect2, varscan2
- EXTL1 | c.519C>A p.F173L | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- EYS | c.4979G>T p.C1660F | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- F13A1 | c.629T>A p.I210N | Missense Mutation (SNP) | VAF 73/411 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- FAM135B | c.3988A>T p.K1330* | Nonsense Mutation (SNP) | VAF 48/275 reads (17%) | called by muse, mutect2, varscan2
- FAT3 | c.6908G>T p.G2303V | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT4 | c.14821G>T p.G4941C | Missense Mutation (SNP) | VAF 49/382 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCSK | c.800A>C p.D267A | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FER1L6 | c.960G>T p.R320S | Missense Mutation (SNP) | VAF 43/276 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FGD6 | c.1401G>T p.L467F | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- FGF20 | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
- FHAD1 | c.3126G>T p.Q1042H | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- FLG | c.3294C>A p.S1098R | Missense Mutation (SNP) | VAF 180/439 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FOXD4L4 | c.703C>A p.P235T | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by mutect2, varscan2
- FOXL2NB | c.479G>T p.W160L | Missense Mutation (SNP) | VAF 133/594 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- FREM3 | c.4189G>C p.D1397H | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRYL | c.4225A>T p.S1409C | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GALP | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 47/202 reads (23%) | called by muse, mutect2, varscan2
- GAPVD1 | c.1975G>T p.V659F | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GATA2 | c.496T>A p.S166T | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GOLIM4 | c.1794G>T p.M598I | Missense Mutation (SNP) | VAF 86/446 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- GON4L | c.3320C>T p.P1107L | Missense Mutation (SNP) | VAF 19/272 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.663); called by muse, mutect2
- GPR148 | c.324del p.S109Afs*156 | Frame Shift Del (DEL) | VAF 55/212 reads (26%) | called by mutect2, pindel, varscan2
- GRIA1 | c.2683C>T p.H895Y | Missense Mutation (SNP) | VAF 93/254 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- GRID1 | c.2161T>A p.C721S | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRIK3 | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | called by muse, varscan2
- GRK1 | c.758T>C p.L253P | Missense Mutation (SNP) | VAF 157/376 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HAS1 | c.1357C>G p.R453G | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- HDAC4 | c.1660G>T p.A554S | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated (0.99); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HECW1 | c.3577G>C p.G1193R | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- HEPACAM2 | c.1097T>A p.M366K (on ENST00000394468 / NM_001039372.4; = p.M354K on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- HIPK1 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HLA-DPA1 | c.456G>T p.W152C | Missense Mutation (SNP) | VAF 108/460 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HLTF | c.244A>T p.M82L | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- HMGN4 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- HPSE | c.841A>T p.S281C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- HRNR | c.1889C>A p.S630* | Nonsense Mutation (SNP) | VAF 253/796 reads (32%) | called by muse, mutect2, varscan2
- HS6ST1 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 46/285 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, varscan2
- IFNAR2 | c.1435C>G p.P479A | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- IFT140 | c.3593G>A p.C1198Y | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- IGDCC4 | c.2839C>A p.L947M | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.326); called by muse, varscan2
- IGDCC4 | c.1669G>T p.G557W | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGF2BP2 | c.444C>A p.Y148* | Nonsense Mutation (SNP) | VAF 26/688 reads (4%) | called by muse, mutect2
- IGHD | c.810G>T p.Q270H | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- IGHV3-20 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 33/457 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.062); called by muse, mutect2
- IGKV3-11 | c.186G>T p.Q62H | Missense Mutation (SNP) | VAF 101/620 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- IMPG1 | c.1367T>C p.I456T | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- INTS2 | c.7-2A>G p.X3_splice | Splice Site (SNP) | VAF 18/107 reads (17%) | called by muse, mutect2, varscan2
- IQCF1 | c.377G>T p.W126L | Missense Mutation (SNP) | VAF 92/229 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- IRF9 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 66/224 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITIH6 | c.2700C>A p.S900R | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- JHY | c.1348G>C p.D450H | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- KALRN | c.97T>C p.S33P | Missense Mutation (SNP) | VAF 35/420 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.176); called by muse, mutect2
- KCNC3 | c.1951G>C p.E651Q | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- KCND3 | c.288C>A p.N96K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- KCNH7 | c.3129C>G p.N1043K | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, varscan2
- KIAA1217 | c.1508G>T p.R503L | Missense Mutation (SNP) | VAF 113/388 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIF4A | c.2183G>C p.R728P | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLHL33 | c.1054G>T p.A352S | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KLHL36 | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KLK3 | c.92G>A p.C31Y | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KMT2D | c.7573_7574del p.G2525Cfs*129 | Frame Shift Del (DEL) | VAF 13/73 reads (18%) | called by mutect2, pindel, varscan2
- KRTAP20-4 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 103/281 reads (37%) | PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KRTAP26-1 | c.336T>A p.C112* | Nonsense Mutation (SNP) | VAF 19/88 reads (22%) | called by muse, mutect2, varscan2
- KRTAP5-10 | c.554C>A p.P185H | Missense Mutation (SNP) | VAF 83/240 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- L1CAM | c.349A>T p.S117C | Missense Mutation (SNP) | VAF 98/176 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LCT | c.721G>T p.D241Y | Missense Mutation (SNP) | VAF 29/352 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.366); called by muse, mutect2
- LGI4 | c.244C>A p.L82I | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LHX1 | c.365G>T p.S122I | Missense Mutation (SNP) | VAF 136/547 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- LRP1 | c.9956C>G p.T3319S | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- LRP2 | c.9861G>C p.L3287F | Missense Mutation (SNP) | VAF 79/322 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- LRRC63 | c.751C>A p.Q251K | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- LRRTM1 | c.522G>T p.Q174H | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- LYST | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- MAGEB5 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- MBOAT1 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 25/293 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2
- MDM4 | c.971G>T p.W324L | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- MED23 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 49/433 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- MGAM2 | c.4518A>T p.T1506= | Splice Region (SNP) | VAF 18/121 reads (15%) | called by muse, mutect2, varscan2
- MGAT4C | c.1368G>T p.M456I | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- MICAL2 | c.653T>A p.V218D | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MON1B | c.1133G>A p.G378D | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- MRC1 | c.4154C>T p.S1385F | Missense Mutation (SNP) | VAF 146/568 reads (26%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- MS4A14 | c.1906G>T p.V636L | Missense Mutation (SNP) | VAF 62/180 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.37484T>A p.L12495Q | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC16 | c.7889C>A p.P2630Q | Missense Mutation (SNP) | VAF 73/266 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MUC16 | c.2017A>G p.T673A | Missense Mutation (SNP) | VAF 62/265 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC19 | c.373C>A p.Q125K | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- MUC5B | c.11501C>A p.S3834Y | Missense Mutation (SNP) | VAF 130/502 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.178); called by muse, varscan2
- MYH4 | c.4289A>C p.E1430A | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MYH7 | c.1064C>A p.A355D | Missense Mutation (SNP) | VAF 77/479 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- MYO18B | c.3132T>A p.H1044Q | Missense Mutation (SNP) | VAF 54/509 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO1E | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 50/403 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NAT10 | c.848C>T p.T283I | Missense Mutation (SNP) | VAF 40/318 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- NDUFS6 | c.225G>T p.Q75H | Missense Mutation (SNP) | VAF 589/1437 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- NLGN1 | c.2070C>A p.N690K | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NR1H4 | c.348G>C p.M116I (on ENST00000551379 / NM_001206993.2; = p.M106I on NM_005123.4) | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- NSD3 | c.2058G>A p.M686I | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- NTHL1 | c.919C>G p.P307A (on ENST00000219066; = p.P299A on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/239 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- NUSAP1 | c.351G>C p.Q117H | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); called by muse, varscan2
- ODF2L | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- OR10D3 | c.371C>T p.T124I | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10J5 | c.806A>T p.K269I | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2
- OR2C3 | c.214A>T p.M72L | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- OR2G3 | c.707A>G p.K236R | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2J3 | c.417G>T p.M139I | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- OR2L2 | c.153C>A p.D51E | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.165); called by muse, mutect2
- OR4A47 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5B3 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- OR5H14 | c.687G>T p.K229N | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- OR5H6 | c.236T>A p.L79H (on ENST00000642105; = p.L63H on NM_001005479.2) | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- OR5T2 | c.329C>G p.A110G | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); called by muse, varscan2
- OR8K3 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- OSGIN2 | c.105A>T p.L35F | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- OSMR | c.1245G>T p.W415C | Missense Mutation (SNP) | VAF 93/479 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OTOGL | c.5125G>C p.G1709R (on ENST00000547103; = p.G1700R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- OVCH1 | c.2567G>T p.G856V | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- P2RY10 | c.422C>A p.A141D | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PCDH1 | c.3247G>A p.A1083T | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PCDH11X | c.3899C>G p.A1300G | Missense Mutation (SNP) | VAF 173/377 reads (46%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHA9 | c.1128C>A p.D376E | Missense Mutation (SNP) | VAF 136/348 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCLO | c.13423C>G p.Q4475E | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); called by mutect2, varscan2
- PDCL3 | c.47A>G p.K16R | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PDZD4 | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PGLYRP2 | c.214G>T p.G72W | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- PHF20L1 | c.2401C>A p.P801T | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PHLDB2 | c.722A>T p.Y241F | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PINK1 | c.675+4A>T | Splice Region (SNP) | VAF 27/154 reads (18%) | called by muse, mutect2, varscan2
- PLEKHA6 | c.178G>C p.V60L | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLPPR4 | c.1249T>A p.L417M | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PMM1 | c.374+1G>A p.X125_splice | Splice Site (SNP) | VAF 30/228 reads (13%) | called by muse, mutect2, varscan2
- POM121 | c.2987C>T p.T996I (on ENST00000434423; = p.T731I on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- PPIP5K2 | c.2286G>T p.Q762H | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRAMEF19 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 82/427 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- PREX2 | c.1444-1G>T p.X482_splice | Splice Site (SNP) | VAF 40/205 reads (20%) | called by muse, mutect2, varscan2
- PRSS23 | c.515C>T p.T172I | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTBP1 | c.370C>A p.Q124K | Missense Mutation (SNP) | VAF 51/215 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- PTCHD4 | c.1371G>T p.W457C | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PXDNL | c.1990A>T p.I664F | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- RAD18 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- RAG1 | c.813G>C p.K271N | Missense Mutation (SNP) | VAF 90/322 reads (28%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- RB1 | c.121del p.D41Tfs*24 | Frame Shift Del (DEL) | VAF 28/89 reads (31%) | called by mutect2, pindel, varscan2
- RBM12B | c.950T>A p.L317* | Nonsense Mutation (SNP) | VAF 22/137 reads (16%) | called by muse, mutect2, varscan2
- RCN1 | c.506del p.P169Hfs*16 | Frame Shift Del (DEL) | VAF 28/150 reads (19%) | called by mutect2, pindel, varscan2
- RP1 | c.247A>T p.I83F | Missense Mutation (SNP) | VAF 67/336 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- RTTN | c.2099G>A p.G700E | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR2 | c.12573C>A p.N4191K | Missense Mutation (SNP) | VAF 70/195 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- RYR3 | c.1903C>A p.L635M | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SASH3 | c.1100C>A p.T367N | Missense Mutation (SNP) | VAF 53/88 reads (60%) | SIFT tolerated (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SCARF2 | c.1424+1G>T p.X475_splice | Splice Site (SNP) | VAF 146/257 reads (57%) | called by muse, mutect2, varscan2
- SCMH1 | c.245G>T p.G82V (on ENST00000326197 / NM_001031694.2; = p.G35V on NM_012236.4) | Missense Mutation (SNP) | VAF 59/304 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCN1A | c.5951del p.P1984Lfs*6 (on ENST00000303395 / NM_001202435.3; = p.P1973Lfs*6 on NM_006920.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/98 reads (18%) | called by mutect2, pindel, varscan2
- SCN8A | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- SDC2 | c.60+2T>A p.X20_splice | Splice Site (SNP) | VAF 30/120 reads (25%) | called by muse, varscan2
- SDCCAG8 | c.1798A>G p.K600E | Missense Mutation (SNP) | VAF 90/262 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- SGCD | c.733C>A p.L245M (on ENST00000435422 / NM_001128209.2; = p.L246M on NM_000337.5) | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SHISA9 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- SHTN1 | c.176C>G p.S59C | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SI | c.922C>G p.P308A | Missense Mutation (SNP) | VAF 54/290 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SIGLEC1 | c.1073A>G p.Y358C | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC12A1 | c.1796C>A p.P599H | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC25A6 | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 77/283 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC28A1 | c.858G>T p.M286I | Missense Mutation (SNP) | VAF 52/328 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- SLC34A3 | c.610C>A p.L204M | Missense Mutation (SNP) | VAF 192/366 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- SLC35B2 | c.1074del p.I359Lfs*13 | Frame Shift Del (DEL) | VAF 55/345 reads (16%) | called by mutect2*, pindel*, varscan2
- SLC4A2 | c.1502A>C p.K501T | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- SLC9A2 | c.264C>G p.I88M | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- SLCO6A1 | c.1306G>T p.G436C | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMG1 | c.7217G>T p.G2406V | Missense Mutation (SNP) | VAF 38/311 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SMG1 | c.7216G>T p.G2406C | Missense Mutation (SNP) | VAF 38/310 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SON | c.5499A>T p.E1833D | Missense Mutation (SNP) | VAF 89/282 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- SPATA31A3 | c.3421G>A p.D1141N | Missense Mutation (SNP) | VAF 49/448 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- SPTB | c.4127C>A p.S1376* | Nonsense Mutation (SNP) | VAF 124/390 reads (32%) | called by muse, mutect2, varscan2
- SUGP1 | c.1684G>C p.V562L | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- SULT1C4 | c.901C>A p.Q301K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2
- SYNE1 | c.16013G>T p.W5338L (on ENST00000367255 / NM_182961.4; = p.W5267L on NM_033071.3) | Missense Mutation (SNP) | VAF 66/345 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYNE2 | c.19970G>T p.R6657L | Missense Mutation (SNP) | VAF 44/309 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SYT16 | c.1229C>A p.P410H | Missense Mutation (SNP) | VAF 116/346 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- SYT9 | c.501T>A p.H167Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TAGLN3 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 29/133 reads (22%) | called by muse, mutect2, varscan2
- TBC1D17 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 96/294 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TBL2 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TCOF1 | c.2191G>T p.V731F (on ENST00000377797 / NM_001135243.1; = p.V654F on NM_000356.4) | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- TENM1 | c.229T>A p.C77S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (0.48); PolyPhen probably damaging (0.977); called by muse, mutect2
- TENM3 | c.2056G>T p.G686C | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- TENM4 | c.685G>T p.A229S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TF | c.418G>T p.G140C | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TFCP2 | c.177T>A p.D59E | Missense Mutation (SNP) | VAF 66/261 reads (25%) | SIFT tolerated (0.96); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TGIF2LX | c.119C>G p.T40R | Missense Mutation (SNP) | VAF 99/245 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TGM5 | c.826G>C p.G276R (on ENST00000220420 / NM_201631.4; = p.G194R on NM_004245.4) | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLR10 | c.949G>T p.D317Y | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- TMCO5A | c.678C>A p.C226* | Nonsense Mutation (SNP) | VAF 20/92 reads (22%) | called by muse, mutect2
- TMEM121B | c.633G>T p.Q211H | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- TMEM202 | c.153G>T p.Q51H | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- TMEM202 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TMEM232 | c.1334C>T p.S445L | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TMPRSS11A | c.124C>A p.L42I | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.072); called by muse, mutect2
- TNFAIP8L3 | c.131T>A p.L44H | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNS4 | c.1962G>T p.M654I | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- TPM4 | c.244-4G>T | Splice Region (SNP) | VAF 122/436 reads (28%) | called by muse, mutect2, varscan2
- TRAPPC10 | c.2381A>T p.D794V | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- TRAV8-3 | c.16A>T p.I6F | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- TRIM56 | c.427A>C p.T143P | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTN | c.78322G>C p.E26108Q (on ENST00000591111; = p.E18684Q on NM_003319.4) | Missense Mutation (SNP) | VAF 50/222 reads (23%) | PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- TTN | c.11917C>A p.L3973I (on ENST00000591111; = p.L3927I on NM_003319.4) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- TTN | c.2944C>G p.Q982E (on ENST00000591111; = p.Q936E on NM_003319.4) | Missense Mutation (SNP) | VAF 39/172 reads (23%) | PolyPhen benign (0.121); called by muse, mutect2, varscan2
- TUT4 | c.283C>G p.H95D | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- UBQLN3 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 81/360 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- UCMA | c.254T>A p.L85Q | Missense Mutation (SNP) | VAF 62/239 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- UGT3A1 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 80/351 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- UMOD | c.277G>C p.V93L | Missense Mutation (SNP) | VAF 89/304 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UNC13B | c.1013C>A p.A338D | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- URAD | c.454G>C p.G152R | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- USHBP1 | c.139G>T p.V47L | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- USP15 | c.1885G>T p.G629* (on ENST00000280377 / NM_001351159.2; = p.G600* on NM_006313.3 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 54/259 reads (21%) | called by muse, mutect2, varscan2
- USP40 | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- VENTX | c.607T>A p.W203R | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- VPS13D | c.7097C>T p.A2366V | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- WASHC2C | c.1019T>G p.L340* | Nonsense Mutation (SNP) | VAF 61/286 reads (21%) | called by muse, mutect2, varscan2
- WDR17 | c.3464A>T p.E1155V | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR81 | c.3409C>G p.L1137V (on ENST00000409644 / NM_001163809.2; = p.L86V on NM_152348.4) | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- XIRP2 | c.5327C>A p.A1776D (on ENST00000628543; = p.A1951D on NM_152381.6) | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZAN | c.1022A>T p.Q341L | Missense Mutation (SNP) | VAF 79/268 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- ZFHX3 | c.9702C>A p.D3234E | Missense Mutation (SNP) | VAF 57/377 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- ZMIZ1 | c.2746C>A p.H916N | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- ZMYM6 | c.1664A>T p.Q555L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- ZNF141 | c.1092G>T p.E364D | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- ZNF17 | c.1807G>T p.V603F | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- ZNF264 | c.1199A>T p.E400V | Missense Mutation (SNP) | VAF 38/370 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ZNF282 | c.80G>C p.W27S | Missense Mutation (SNP) | VAF 89/195 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- ZNF345 | c.1130A>G p.K377R | Missense Mutation (SNP) | VAF 76/279 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF426 | c.1278del p.V428Yfs*134 | Frame Shift Del (DEL) | VAF 22/114 reads (19%) | called by mutect2, pindel, varscan2
- ZNF568 | c.1363G>C p.E455Q | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- ZNF639 | c.119A>C p.Y40S | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZNF709 | c.1024G>T p.G342W | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF804A | c.794C>A p.T265K | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ZNF844 | c.593A>C p.K198T | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ZNF853 | c.1469G>C p.C490S | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZPLD1 | c.1175C>A p.S392* (on ENST00000466937 / NM_001329788.1; = p.S408* on NM_175056.2) | Nonsense Mutation (SNP) | VAF 46/214 reads (21%) | called by muse, mutect2, varscan2
- ZRANB2 | c.929+1G>A p.X310_splice | Splice Site (SNP) | VAF 25/147 reads (17%) | called by muse, varscan2
- ZSCAN31 | c.1103A>T p.Q368L | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- AAK1 | c.1326A>T p.P442= | Silent (SNP) | VAF 44/260 reads (17%) | called by muse, mutect2, varscan2
- ABCA13 | c.7470C>T p.H2490= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as rs778470798; called by muse, mutect2, varscan2
- ABCA4 | c.1041C>T p.A347= | Silent (SNP) | VAF 92/390 reads (24%) | called by muse, mutect2, varscan2
- ADAM33 | c.924C>A p.G308= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100597996; called by muse, mutect2, varscan2
- ADAMTS16 | c.624C>A p.S208= | Silent (SNP) | VAF 228/562 reads (41%) | catalogued as rs761790579; called by muse, mutect2, varscan2
- ADGRL4 | c.363T>C p.C121= | Silent (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- ADIPOQ | c.90C>A p.P30= | Silent (SNP) | VAF 12/211 reads (6%) | called by muse, mutect2
- ADRB1 | c.459C>A p.A153= | Silent (SNP) | VAF 98/242 reads (40%) | called by muse, mutect2, varscan2
- ALG14 | c.393C>T p.P131= | Silent (SNP) | VAF 48/204 reads (24%) | catalogued as COSV100930841; called by muse, mutect2, varscan2
- ANKS4B | c.1179G>A p.K393= | Silent (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- ASNSD1 | c.90G>T p.R30= | Silent (SNP) | VAF 32/122 reads (26%) | called by muse, mutect2, varscan2
- ATP9B | c.2595A>T p.T865= | Silent (SNP) | VAF 35/176 reads (20%) | called by muse, mutect2, varscan2
- BAG4 | c.624G>T p.P208= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as COSV54863088; called by muse, mutect2, varscan2
- BCORL1 | c.2172G>T p.V724= | Silent (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- BOP1 | c.2208G>A p.S736= | Silent (SNP) | VAF 41/481 reads (9%) | catalogued as rs1264504557; called by muse, mutect2
- C1orf109 | c.210A>G p.K70= | Silent (SNP) | VAF 31/111 reads (28%) | called by muse, mutect2, varscan2
- C8G | c.604A>C p.R202= | Silent (SNP) | VAF 108/241 reads (45%) | called by muse, mutect2, varscan2
- CACNG1 | c.78C>G p.A26= | Silent (SNP) | VAF 43/351 reads (12%) | catalogued as rs771970095, COSV56827826; called by muse, mutect2, varscan2
- CALHM6 | c.228C>A p.R76= | Silent (SNP) | VAF 26/130 reads (20%) | called by muse, mutect2, varscan2
- CCDC74B | c.72C>A p.R24= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs766312821; called by muse, mutect2, varscan2
- CCNF | c.1815C>T p.L605= | Silent (SNP) | VAF 24/151 reads (16%) | catalogued as rs761837003; called by muse, mutect2, varscan2
- CD207 | c.528C>A p.G176= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as COSV69652691; called by muse, mutect2, varscan2
- CD300LG | c.139C>A p.R47= | Silent (SNP) | VAF 118/341 reads (35%) | catalogued as rs187296668; called by muse, mutect2, varscan2
- CELA1 | c.354C>A p.A118= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as COSV53331337; called by muse, mutect2, varscan2
- CELA2B | c.798T>A p.I266= | Silent (SNP) | VAF 47/241 reads (20%) | called by muse, mutect2, varscan2
- CELSR3 | c.3357C>T p.I1119= | Silent (SNP) | VAF 26/159 reads (16%) | catalogued as rs139204064; called by mutect2, varscan2
- CENPE | c.4350G>T p.L1450= | Silent (SNP) | VAF 43/146 reads (29%) | catalogued as COSV54379566; called by muse, mutect2, varscan2
- CENPE | c.3936A>G p.T1312= | Silent (SNP) | VAF 44/255 reads (17%) | catalogued as rs1483756548; called by muse, mutect2, varscan2
- CHRNA4 | c.1176C>G p.P392= | Silent (SNP) | VAF 15/82 reads (18%) | called by muse, mutect2, varscan2
- CHSY1 | c.429C>T p.Y143= | Silent (SNP) | VAF 35/239 reads (15%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.378G>A p.E126= | Silent (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2
- CNTNAP4 | c.642C>A p.T214= | Silent (SNP) | VAF 42/195 reads (22%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.1980G>T p.V660= | Silent (SNP) | VAF 49/161 reads (30%) | called by muse, mutect2, varscan2
- COL5A3 | c.1920G>T p.P640= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs769567123, COSV53408727; called by muse, mutect2, varscan2
- CR1L | c.642G>T p.V214= | Silent (SNP) | VAF 129/373 reads (35%) | called by muse, mutect2, varscan2
- CRB2 | c.3165C>A p.R1055= | Silent (SNP) | VAF 60/96 reads (63%) | called by muse, mutect2, varscan2
- CSMD1 | c.858C>T p.S286= | Silent (SNP) | VAF 47/176 reads (27%) | catalogued as rs777346120; called by muse, mutect2, varscan2
- CSMD2 | c.8010C>A p.I2670= | Silent (SNP) | VAF 39/153 reads (25%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.1143G>T p.L381= | Silent (SNP) | VAF 10/60 reads (17%) | called by muse, mutect2
- DCX | c.744G>T p.V248= | Silent (SNP) | VAF 63/147 reads (43%) | called by muse, mutect2, varscan2
- DDX51 | c.1989G>A p.Q663= | Silent (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- DISP3 | c.2973C>T p.C991= | Silent (SNP) | VAF 52/166 reads (31%) | catalogued as rs768671644; called by muse, mutect2, varscan2
- DOCK2 | c.1758C>A p.S586= | Silent (SNP) | VAF 37/84 reads (44%) | called by muse, mutect2, varscan2
- DPRX | c.405C>A p.P135= | Silent (SNP) | VAF 28/170 reads (16%) | catalogued as rs565196699, COSV64949152; called by muse, mutect2, varscan2
- DSG3 | c.690T>C p.A230= | Silent (SNP) | VAF 18/173 reads (10%) | called by muse, mutect2, varscan2
- DYSF | c.1728T>A p.P576= | Silent (SNP) | VAF 38/179 reads (21%) | called by muse, mutect2, varscan2
- ECI2 | c.1080A>G p.L360= (on ENST00000380118 / NM_206836.3; = p.L330= on NM_006117.2) | Silent (SNP) | VAF 21/159 reads (13%) | called by muse, mutect2, varscan2
- EFCAB5 | c.3279C>A p.S1093= | Silent (SNP) | VAF 69/223 reads (31%) | called by muse, mutect2, varscan2
- EFTUD2 | c.2409G>T p.R803= | Silent (SNP) | VAF 85/248 reads (34%) | called by muse, mutect2, varscan2
- EIF5B | c.492A>C p.S164= | Silent (SNP) | VAF 37/136 reads (27%) | called by muse, mutect2, varscan2
- EPHX3 | c.36G>T p.P12= | Silent (SNP) | VAF 67/246 reads (27%) | called by muse, mutect2, varscan2
- ESRRB | c.1029G>T p.T343= | Silent (SNP) | VAF 16/63 reads (25%) | called by muse, mutect2, varscan2
- ESRRG | c.147G>T p.L49= | Silent (SNP) | VAF 14/238 reads (6%) | called by muse, mutect2
- EVX2 | c.642G>T p.S214= | Silent (SNP) | VAF 29/141 reads (21%) | catalogued as rs781605883; called by muse, mutect2, varscan2
- EXOC6B | c.1929A>T p.V643= | Silent (SNP) | VAF 56/334 reads (17%) | called by muse, mutect2, varscan2
- EYA4 | c.201G>T p.G67= | Silent (SNP) | VAF 70/289 reads (24%) | called by muse, mutect2, varscan2
- FAIM2 | c.828G>T p.L276= | Silent (SNP) | VAF 51/172 reads (30%) | called by muse, mutect2, varscan2
- FAM186A | c.6939C>A p.L2313= | Silent (SNP) | VAF 41/188 reads (22%) | called by muse, mutect2, varscan2
- FAT4 | c.1902G>C p.L634= | Silent (SNP) | VAF 30/192 reads (16%) | catalogued as rs1262186793, COSV67881434; called by muse, mutect2, varscan2
- FGF23 | c.258A>T p.T86= | Silent (SNP) | VAF 99/343 reads (29%) | called by muse, mutect2, varscan2
- FOXD3 | c.1356C>T p.L452= | Silent (SNP) | VAF 115/452 reads (25%) | called by muse, mutect2, varscan2
- GLT8D2 | c.471T>C p.D157= | Silent (SNP) | VAF 28/154 reads (18%) | called by muse, mutect2, varscan2
- GOLGA6L2 | c.2136G>T p.T712= | Silent (SNP) | VAF 42/370 reads (11%) | called by muse, varscan2
- GPM6A | c.273G>T p.A91= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as rs758575502, COSV54534194; called by muse, mutect2, varscan2
- GPR42 | c.655C>A p.R219= | Silent (SNP) | VAF 68/184 reads (37%) | called by muse, mutect2, varscan2
- GRID1 | c.795G>T p.P265= | Silent (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2
- GUSB | c.393C>T p.I131= | Silent (SNP) | VAF 22/160 reads (14%) | catalogued as rs1452631377; called by muse, mutect2, varscan2
- HCN4 | c.1461G>T p.V487= | Silent (SNP) | VAF 41/234 reads (18%) | called by muse, mutect2, varscan2
- HTR1B | c.513G>T p.A171= | Silent (SNP) | VAF 86/276 reads (31%) | called by muse, mutect2, varscan2
- IL17A | c.435C>A p.T145= | Silent (SNP) | VAF 33/136 reads (24%) | called by muse, mutect2, varscan2
- IL2RB | c.984G>C p.L328= | Silent (SNP) | VAF 14/143 reads (10%) | called by muse, mutect2, varscan2
- INTS1 | c.5196C>T p.L1732= | Silent (SNP) | VAF 27/143 reads (19%) | called by muse, mutect2, varscan2
- IQCN | c.2295C>T p.L765= | Silent (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2, varscan2
- JAK2 | c.276A>G p.E92= | Silent (SNP) | VAF 23/102 reads (23%) | called by muse, mutect2, varscan2
- KAT6A | c.5586G>A p.A1862= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs199854130; called by muse, mutect2, varscan2
- KCNA4 | c.238C>A p.R80= | Silent (SNP) | VAF 19/136 reads (14%) | catalogued as COSV60251867; called by muse, mutect2, varscan2
- KCNH1 | c.2880C>T p.S960= (on ENST00000271751 / NM_172362.3; = p.S933= on NM_002238.4) | Silent (SNP) | VAF 118/333 reads (35%) | called by muse, mutect2, varscan2
- KIAA1549L | c.4944T>C p.P1648= (on ENST00000321505; = p.P1945= on NM_012194.3) | Silent (SNP) | VAF 27/246 reads (11%) | called by muse, mutect2, varscan2
- KIF4A | c.1212T>A p.R404= | Silent (SNP) | VAF 76/136 reads (56%) | called by muse, mutect2, varscan2
- KIF4A | c.2184G>T p.R728= | Silent (SNP) | VAF 41/96 reads (43%) | called by muse, mutect2, varscan2
- KIF7 | c.1107G>C p.A369= | Silent (SNP) | VAF 32/128 reads (25%) | called by muse, mutect2, varscan2
- KRTAP5-11 | c.99C>A p.S33= | Silent (SNP) | VAF 101/244 reads (41%) | called by muse, mutect2, varscan2
- LAMA1 | c.3822A>C p.A1274= | Silent (SNP) | VAF 128/394 reads (32%) | called by muse, mutect2, varscan2
- LRRC37B | c.1608C>G p.L536= | Silent (SNP) | VAF 38/384 reads (10%) | called by muse, mutect2, varscan2
- MALRD1 | c.5502G>T p.G1834= | Silent (SNP) | VAF 59/283 reads (21%) | catalogued as rs945495452; called by muse, mutect2, varscan2
- MCF2 | c.1614G>T p.L538= | Silent (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- MED1 | c.936A>T p.P312= | Silent (SNP) | VAF 29/281 reads (10%) | called by muse, mutect2, varscan2
- MFSD2B | c.669C>G p.V223= | Silent (SNP) | VAF 18/73 reads (25%) | called by muse, varscan2
- MIB2 | c.123C>T p.P41= | Silent (SNP) | VAF 31/271 reads (11%) | called by muse, mutect2, varscan2
- MICAL2 | c.1737C>T p.L579= | Silent (SNP) | VAF 40/278 reads (14%) | catalogued as rs754326645; called by muse, mutect2, varscan2
- MUC16 | c.32655T>A p.S10885= | Silent (SNP) | VAF 27/86 reads (31%) | called by muse, mutect2, varscan2
- MUC3A | c.9066C>A p.T3022= | Silent (SNP) | VAF 32/270 reads (12%) | called by muse, mutect2
- MUC5B | c.7257C>T p.A2419= | Silent (SNP) | VAF 57/192 reads (30%) | called by muse, mutect2, varscan2
- MUC5B | c.8736C>A p.P2912= | Silent (SNP) | VAF 10/194 reads (5%) | called by muse, mutect2
- MUC5B | c.12507C>A p.P4169= | Silent (SNP) | VAF 52/266 reads (20%) | called by muse, varscan2
- MUC6 | c.3906C>A p.T1302= | Silent (SNP) | VAF 137/472 reads (29%) | called by muse, mutect2, varscan2
- MYBPC3 | c.1734G>A p.L578= | Silent (SNP) | VAF 40/219 reads (18%) | catalogued as COSV57026274; called by muse, mutect2, varscan2
- MYLK | c.2934C>T p.T978= | Silent (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- MYO1B | c.843G>A p.L281= | Silent (SNP) | VAF 18/240 reads (8%) | called by muse, mutect2
- NAV2 | c.981G>A p.P327= (on ENST00000396087 / NM_001244963.2; = p.P304= on NM_145117.5) | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as rs764942693, COSV62335603; called by muse, mutect2, varscan2
- NCSTN | c.366A>G p.A122= | Silent (SNP) | VAF 89/290 reads (31%) | called by muse, mutect2, varscan2
- NLGN3 | c.828G>C p.G276= (on ENST00000358741 / NM_181303.2; = p.G256= on NM_018977.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/83 reads (55%) | called by muse, mutect2, varscan2
- NLRP14 | c.2895G>T p.G965= | Silent (SNP) | VAF 73/316 reads (23%) | catalogued as rs1174749460, COSV55067151; called by muse, mutect2, varscan2
- NLRP3 | c.1548C>T p.Y516= | Silent (SNP) | VAF 23/296 reads (8%) | catalogued as rs1226573823; called by muse, mutect2
- NSD1 | c.3402C>T p.G1134= | Silent (SNP) | VAF 37/115 reads (32%) | called by muse, mutect2, varscan2
- OBSCN | c.3385C>A p.R1129= | Silent (SNP) | VAF 38/374 reads (10%) | called by muse, mutect2
- OR10H5 | c.156G>A p.E52= | Silent (SNP) | VAF 16/171 reads (9%) | called by muse, mutect2, varscan2
- OR56B4 | c.540C>T p.I180= | Silent (SNP) | VAF 27/133 reads (20%) | catalogued as rs772357495, COSV57205891; called by muse, mutect2, varscan2
- OR7C1 | c.678G>A p.L226= | Silent (SNP) | VAF 38/188 reads (20%) | catalogued as rs747404880; called by muse, mutect2, varscan2
- OR8H1 | c.741C>T p.V247= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as COSV57295881; called by muse, mutect2, varscan2
- OR9I1 | c.825T>G p.S275= | Silent (SNP) | VAF 73/303 reads (24%) | called by muse, mutect2, varscan2
- PCNX1 | c.2400G>T p.G800= | Silent (SNP) | VAF 59/199 reads (30%) | called by muse, mutect2, varscan2
- PDCD1 | c.589C>A p.R197= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as rs1282191832, COSV57691336; called by muse, mutect2, varscan2
- PDZD4 | c.918C>T p.T306= | Silent (SNP) | VAF 57/105 reads (54%) | called by muse, mutect2, varscan2
- PEG3 | c.3177T>C p.H1059= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV55635180; called by muse, mutect2, varscan2
- PKD1L1 | c.5241C>T p.H1747= | Silent (SNP) | VAF 36/144 reads (25%) | catalogued as rs1193610728; called by muse, mutect2, varscan2
- PLXNA4 | c.3420C>A p.P1140= | Silent (SNP) | VAF 107/300 reads (36%) | called by muse, mutect2, varscan2
- PNMT | c.685C>T p.L229= | Silent (SNP) | VAF 73/302 reads (24%) | called by muse, mutect2, varscan2
- PNPT1 | c.993C>T p.A331= | Silent (SNP) | VAF 8/95 reads (8%) | catalogued as rs147013543, COSV53178232; called by muse, mutect2
- POM121 | c.3657G>A p.S1219= (on ENST00000434423; = p.S954= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/136 reads (20%) | catalogued as rs527603232; called by muse, mutect2, varscan2
- PPWD1 | c.1737C>T p.S579= | Silent (SNP) | VAF 21/135 reads (16%) | called by muse, mutect2, varscan2
- PROX1 | c.1500C>T p.P500= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs753142345; called by muse, mutect2, varscan2
- PRR33 | c.501C>T p.F167= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as rs748663413; called by muse, mutect2, varscan2
- PSMD5 | c.39G>A p.A13= | Silent (SNP) | VAF 63/121 reads (52%) | catalogued as rs1488419444; called by muse, mutect2, varscan2
- PTCRA | c.543C>T p.S181= | Silent (SNP) | VAF 93/337 reads (28%) | catalogued as rs919491650; called by muse, mutect2, varscan2
- RAD51AP2 | c.1101C>T p.F367= | Silent (SNP) | VAF 23/203 reads (11%) | catalogued as COSV67589222; called by muse, mutect2, varscan2
- RELT | c.867G>T p.S289= | Silent (SNP) | VAF 95/275 reads (35%) | catalogued as COSV50361123; called by muse, mutect2, varscan2
- RGS14 | c.1015C>T p.L339= | Silent (SNP) | VAF 63/294 reads (21%) | called by muse, mutect2, varscan2
- RLN3 | c.144G>C p.G48= | Silent (SNP) | VAF 40/150 reads (27%) | called by muse, mutect2, varscan2
- RNF26 | c.789C>A p.A263= | Silent (SNP) | VAF 81/224 reads (36%) | called by muse, mutect2, varscan2
- RNF40 | c.1251G>T p.L417= | Silent (SNP) | VAF 21/65 reads (32%) | called by muse, mutect2, varscan2
- RRBP1 | c.2667G>T p.R889= (on ENST00000377813 / NM_001365613.2; = p.R456= on NM_004587.3) | Silent (SNP) | VAF 65/191 reads (34%) | called by muse, mutect2, varscan2
- SCN3A | c.4209T>C p.V1403= | Silent (SNP) | VAF 36/121 reads (30%) | called by muse, mutect2, varscan2
- SLC17A8 | c.1464C>A p.A488= | Silent (SNP) | VAF 41/197 reads (21%) | called by muse, mutect2, varscan2
- SLC24A5 | c.54C>A p.I18= | Silent (SNP) | VAF 19/111 reads (17%) | called by muse, mutect2, varscan2
- SLC37A3 | c.1131T>A p.S377= | Silent (SNP) | VAF 34/118 reads (29%) | called by muse, varscan2
- SLC8A1 | c.2607C>T p.N869= | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as rs973055147, COSV60484597, COSV60489711; called by muse, mutect2, varscan2
- SLCO5A1 | c.1233G>C p.S411= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as COSV52670171; called by muse, mutect2, varscan2
- SPEM2 | c.1227G>A p.E409= | Silent (SNP) | VAF 53/122 reads (43%) | called by muse, mutect2, varscan2
- SSC5D | c.753C>A p.A251= | Silent (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- SSTR3 | c.528G>T p.L176= | Silent (SNP) | VAF 20/35 reads (57%) | called by muse, mutect2, varscan2
- SSTR5 | c.822G>T p.V274= | Silent (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- STAT4 | c.1761A>T p.L587= | Silent (SNP) | VAF 43/193 reads (22%) | called by muse, mutect2, varscan2
- STT3B | c.1221A>G p.Q407= | Silent (SNP) | VAF 102/271 reads (38%) | catalogued as rs754086891, COSV55502591; called by muse, mutect2, varscan2
- TBC1D2B | c.1380C>T p.G460= | Silent (SNP) | VAF 10/200 reads (5%) | catalogued as COSV100317081; called by muse, mutect2
- TDRD6 | c.396G>C p.A132= | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as rs1370960769, COSV60178996; called by muse, mutect2, varscan2
- TECPR1 | c.1716G>T p.P572= | Silent (SNP) | VAF 48/138 reads (35%) | called by muse, mutect2, varscan2
- TEDC1 | c.1365G>T p.L455= (on ENST00000392523 / NM_001367178.1; = p.L386= on NM_001134875.1) | Silent (SNP) | VAF 97/292 reads (33%) | catalogued as COSV100322372; called by muse, mutect2, varscan2
- TENM1 | c.7647G>T p.R2549= | Silent (SNP) | VAF 56/133 reads (42%) | catalogued as COSV64424773; called by muse, mutect2, varscan2
- TEX13C | c.2835C>A p.S945= | Silent (SNP) | VAF 86/196 reads (44%) | called by muse, mutect2, varscan2
- TEX47 | c.510C>A p.V170= | Silent (SNP) | VAF 29/107 reads (27%) | catalogued as COSV51879723; called by muse, mutect2, varscan2
- TFAP2A | c.144C>T p.S48= (on ENST00000482890; = p.S40= on NM_001032280.3) | Silent (SNP) | VAF 47/121 reads (39%) | called by muse, mutect2, varscan2
- TICRR | c.3519C>T p.I1173= | Silent (SNP) | VAF 33/175 reads (19%) | called by muse, mutect2, varscan2
- TMPRSS11A | c.126A>T p.L42= | Silent (SNP) | VAF 24/116 reads (21%) | called by muse, mutect2
- TPSAB1 | c.66A>T p.P22= | Silent (SNP) | VAF 8/36 reads (22%) | called by muse, varscan2
- TRHDE | c.1650G>A p.L550= | Silent (SNP) | VAF 34/161 reads (21%) | catalogued as COSV99669810; called by muse, mutect2, varscan2
- TTK | c.384A>G p.A128= | Silent (SNP) | VAF 62/236 reads (26%) | called by muse, mutect2, varscan2
- UNCX | c.795G>A p.A265= | Silent (SNP) | VAF 6/56 reads (11%) | called by mutect2, varscan2
- WDR37 | c.93G>A p.S31= | Silent (SNP) | VAF 110/321 reads (34%) | called by muse, mutect2, varscan2
- ZAN | c.5208C>T p.D1736= | Silent (SNP) | VAF 12/184 reads (7%) | catalogued as rs745913008; called by muse, mutect2
- ZMAT3 | c.342C>T p.S114= | Silent (SNP) | VAF 35/412 reads (8%) | catalogued as rs1225570368; called by muse, mutect2
- ZNFX1 | c.1965G>T p.V655= | Silent (SNP) | VAF 32/118 reads (27%) | called by muse, mutect2, varscan2
- ABCC6P2 | n.165C>T | RNA (SNP) | VAF 34/259 reads (13%) | called by muse, mutect2, varscan2
- ABHD4 | c.23+150C>A | Intron (SNP) | VAF 26/140 reads (19%) | called by muse, varscan2
- AC010266.2 | n.1974G>T | RNA (SNP) | VAF 11/130 reads (8%) | called by muse, mutect2
- AC068633.1 | n.204C>G | RNA (SNP) | VAF 21/141 reads (15%) | called by muse, mutect2, varscan2
- AC136759.1 | n.1293G>C | RNA (SNP) | VAF 55/157 reads (35%) | called by muse, mutect2
- ACBD5 | chr10:27196488 G>A | 3'Flank (SNP) | VAF 21/227 reads (9%) | called by muse, mutect2
- AMH | c.555+31G>T | Intron (SNP) | VAF 28/88 reads (32%) | called by muse, mutect2, varscan2
- ANKRD11 | c.7470+46G>T | Intron (SNP) | VAF 15/88 reads (17%) | called by muse, mutect2, varscan2
- ARL13B | c.-12G>T | 5'UTR (SNP) | VAF 70/325 reads (22%) | called by muse, mutect2, varscan2
- ATP11A | c.*10-1302A>T | Intron (SNP) | VAF 132/303 reads (44%) | called by muse, mutect2, varscan2
- ATXN3 | chr14:92106576 del C | 5'Flank (DEL) | VAF 22/124 reads (18%) | called by mutect2, pindel, varscan2
- BROX | c.-149G>T | 5'UTR (SNP) | VAF 15/148 reads (10%) | called by muse, mutect2
- CACTIN | c.*19+124G>T | Intron (SNP) | VAF 33/114 reads (29%) | called by muse, mutect2, varscan2
- CBFA2T2 | c.62-6542C>T | Intron (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- CCDC115 | c.431-453G>T | Intron (SNP) | VAF 47/178 reads (26%) | called by muse, mutect2, varscan2
- CD9 | c.274-12G>A | Intron (SNP) | VAF 40/196 reads (20%) | catalogued as rs191111527; called by muse, mutect2, varscan2
- CDH13 | c.45+77929C>T | Intron (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2, varscan2
- CHIT1 | c.*645T>A | 3'UTR (SNP) | VAF 155/446 reads (35%) | called by muse, mutect2, varscan2
- CXADRP2 | n.604C>A | RNA (SNP) | VAF 22/211 reads (10%) | catalogued as rs761407106; called by mutect2, varscan2
- DHODH | chr16:72008682 G>T | 5'Flank (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2, varscan2
- DPY19L2P2 | n.2934A>T | RNA (SNP) | VAF 9/121 reads (7%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.13515+20G>C | Intron (SNP) | VAF 75/410 reads (18%) | called by muse, mutect2, varscan2
- ERMN | c.-8C>T | 5'UTR (SNP) | VAF 17/102 reads (17%) | catalogued as rs374919878; called by muse, mutect2, varscan2
- EVX2 | c.*4C>T | 3'UTR (SNP) | VAF 25/127 reads (20%) | called by muse, varscan2
- FOXP2 | c.*1161C>G | 3'UTR (SNP) | VAF 62/277 reads (22%) | called by muse, mutect2, varscan2
- FOXP2 | c.*1162C>G | 3'UTR (SNP) | VAF 61/276 reads (22%) | called by muse, mutect2, varscan2
- FXR1 | c.51+2888A>T | Intron (SNP) | VAF 140/379 reads (37%) | called by muse, mutect2, varscan2
- GNG2 | c.-35del | 5'UTR (DEL) | VAF 24/219 reads (11%) | called by mutect2, pindel, varscan2
- GOLGA3 | c.-25C>T | 5'UTR (SNP) | VAF 42/153 reads (27%) | called by muse, mutect2, varscan2
- GOLGA3 | c.-26T>G | 5'UTR (SNP) | VAF 43/153 reads (28%) | called by muse, mutect2, varscan2
- HBS1L | c.430+2156G>A | Intron (SNP) | VAF 12/90 reads (13%) | called by muse, mutect2
- HIPK1 | chr1:113929398 C>A | 5'Flank (SNP) | VAF 66/278 reads (24%) | catalogued as rs1558118229; called by muse, mutect2, varscan2
- HOXA1 | c.-28T>G | 5'UTR (SNP) | VAF 62/295 reads (21%) | called by muse, mutect2, varscan2
- HOXB6 | c.-78-2270G>A | Intron (SNP) | VAF 14/505 reads (3%) | catalogued as rs1453463165; called by muse, mutect2
- IFT43 | chr14:76084027 G>T | 3'Flank (SNP) | VAF 27/64 reads (42%) | called by muse, mutect2, varscan2
- ITIH1 | c.573+29C>T | Intron (SNP) | VAF 60/151 reads (40%) | called by muse, mutect2, varscan2
- KIF13A | c.1786+3873G>T | Intron (SNP) | VAF 25/145 reads (17%) | called by muse, mutect2, varscan2
- KLF6 | c.-22G>T | 5'UTR (SNP) | VAF 48/109 reads (44%) | catalogued as COSV51493719; called by muse, mutect2, varscan2
- LINC00239 | n.137G>C | RNA (SNP) | VAF 56/188 reads (30%) | catalogued as rs1373790558; called by muse, mutect2, varscan2
- LINC02817 | n.530C>A | RNA (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- MFSD4B | c.*1127G>T | 3'UTR (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- MGAT5B | c.69-19G>A | Intron (SNP) | VAF 61/313 reads (19%) | catalogued as rs569753276, COSV56932897; called by muse, mutect2, varscan2
- MLLT6 | c.3241-46G>T | Intron (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.1363G>A | RNA (SNP) | VAF 81/353 reads (23%) | called by muse, mutect2, varscan2
- NCCRP1 | c.-3G>A | 5'UTR (SNP) | VAF 83/232 reads (36%) | catalogued as rs1016718712; called by muse, mutect2, varscan2
- NCF1B | n.574G>T | RNA (SNP) | VAF 30/96 reads (31%) | called by mutect2, varscan2
- NCF1B | n.575G>T | RNA (SNP) | VAF 30/96 reads (31%) | called by mutect2, varscan2
- NCF4 | c.758+84C>T | Intron (SNP) | VAF 50/447 reads (11%) | called by muse, mutect2, varscan2
- OLFM1 | chr9:135087432 G>T | 5'Flank (SNP) | VAF 34/59 reads (58%) | called by muse, mutect2, varscan2
- PARP15 | c.-2G>T | 5'UTR (SNP) | VAF 30/330 reads (9%) | called by muse, mutect2
- PARPBP | c.387+1831A>T | Intron (SNP) | VAF 19/82 reads (23%) | called by muse, varscan2
- PARPBP | c.387+1852G>A | Intron (SNP) | VAF 18/66 reads (27%) | called by muse, varscan2
- PKD1P6 | n.4309G>C | RNA (SNP) | VAF 68/534 reads (13%) | called by muse, varscan2
- PML | c.1710+1527T>G | Intron (SNP) | VAF 76/371 reads (20%) | called by muse, mutect2, varscan2
- PPFIA2 | c.645+56C>A | Intron (SNP) | VAF 30/151 reads (20%) | called by muse, mutect2, varscan2
- RN7SL214P | chr15:77919197 C>A | 5'Flank (SNP) | VAF 56/398 reads (14%) | called by muse, mutect2, varscan2
- SERPINA7 | c.-51T>A | 5'UTR (SNP) | VAF 19/35 reads (54%) | called by muse, mutect2, varscan2
- SLC30A3 | chr2:27264070 G>T | 5'Flank (SNP) | VAF 79/242 reads (33%) | called by muse, mutect2, varscan2
- SMARCA1 | c.*173del | 3'UTR (DEL) | VAF 42/103 reads (41%) | called by mutect2, pindel, varscan2
- SNORD116-22 | chr15:25092111 A>T | 3'Flank (SNP) | VAF 31/145 reads (21%) | called by muse, mutect2, varscan2
- SP140 | c.-11A>T | 5'UTR (SNP) | VAF 85/274 reads (31%) | called by muse, mutect2, varscan2
- SQLE | c.-764G>T | 5'UTR (SNP) | VAF 45/192 reads (23%) | called by muse, mutect2, varscan2
- STX2 | c.280+568C>G | Intron (SNP) | VAF 23/107 reads (21%) | called by muse, mutect2, varscan2
- TCP10L3 | n.2715G>C | RNA (SNP) | VAF 50/270 reads (19%) | catalogued as COSV64749650; called by muse, mutect2, varscan2
- THBS1 | c.*386G>A | 3'UTR (SNP) | VAF 27/212 reads (13%) | catalogued as rs752273610; called by muse, mutect2, varscan2
- TMEM132E | chr17:34579237 C>G | 5'Flank (SNP) | VAF 33/86 reads (38%) | called by muse, mutect2, varscan2
- TRAP1 | chr16:3717547 C>A | 5'Flank (SNP) | VAF 26/80 reads (33%) | catalogued as rs991546908; called by muse, mutect2, varscan2
- UBE2DNL | n.485C>A | RNA (SNP) | VAF 35/59 reads (59%) | called by muse, mutect2, varscan2
- UGT2B27P | n.1524C>A | RNA (SNP) | VAF 38/287 reads (13%) | catalogued as rs750738555; called by muse, mutect2, varscan2
- VWA5B1 | c.710-127G>T | Intron (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2
- WDR70 | c.*9A>G | 3'UTR (SNP) | VAF 46/299 reads (15%) | catalogued as rs747114725; called by muse, mutect2, varscan2
- ZEB2 | c.73+4358G>T | Intron (SNP) | VAF 53/307 reads (17%) | called by muse, mutect2, varscan2
- ZNF107 | c.*1052G>A | 3'UTR (SNP) | VAF 24/187 reads (13%) | called by muse, mutect2, varscan2
- ZNF391 | c.-284C>G | 5'UTR (SNP) | VAF 33/122 reads (27%) | called by muse, mutect2, varscan2
